Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4167, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4167-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Laparoscopic right radical nephrectomy.

Specimens Submitted:

1: SP: Right kidney and partial adrenal

DIAGNOSIS:

- 1) KIDNEY, RIGHT AND ADRENAL; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE (CONVENTIONAL TYPE), NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR AND SOLID.
- THE TUMOR GREATEST DIAMETER IS 4.5 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE.
- [REDACTED]
- [REDACTED]
- [REDACTED]

1) The specimen is received fresh, labeled "Right Kidney and Partial Adrenal". It consists of a kidney with perinephric fat measuring 24 x 13 x 5 cm. Adrenal gland is identified measuring 3.2 x 1.2 cm and is grossly unremarkable. On cut section, the kidney measures 11.8 x 6 cm. A portion of ureter is attached measuring 6 x 0.3 cm and is grossly unremarkable. Cut surface of the kidney reveals a rather well-defined and lobulated tumor located in the outer quadrant of the lower pole of the kidney. The tumor measures 4.5 x 4.3 cm and is composed of multiple yellow-tan, hemorrhagic lobules separated by white-tan, fibrous bands. The tumor grossly seems to extend outside the kidney into the perinephric fat. The tumor approaches upon the renal pelvis. The fat is increased in the renal pelvis. The calyces in the area of the tumor are destroyed. The surrounding calyces are grossly unremarkable. Renal parenchyma is unremarkable. The mucosa of the renal pelvis and ureter is smooth and shiny. Cut section of the perinephric fat, except for the area of tumor, is also unremarkable. Tissue is submitted for TPS and EM.

Summary of Sections:

AG – adrenal gland
UM – ureteral margin
RVM – renal vessel margin
TF – tumor with surrounding fat
T – tumor
R – random kidney
PNF – perinephric fat

[page 2 of 2]
Summary of Sections:

Part 1: SP: Right kidney and partial adrena

Block	Sect. Site	PCs
1	AG	1
1	PNF	1
1	R	1
1	RVM	1
5	T	5
2	TF	2
1	UM	1

Source: NCI Genomic Data Commons file bdcfeb5f-7faf-4019-bc77-960281875af5 (TCGA-BP-4167.70CA2037-D2DD-426A-93BE-B3838CB30282.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).